Surgical pathology report (de-identified scan), TCGA case TCGA-KS-A41I, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Of Michigan, specimen TCGA-KS-A41I-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

ICD-O-3
Carcinoma, papillary, follicular
variant
Site: thyroid, NOS
C73.9 7-22-12 PD
884013

ACCESSION: [REDACTED]

OPER DATE:

REQ DOC: [REDACTED]

PROCEDURE: SPHS

VERIFIED BY: [REDACTED]

year-old with significant PMH with right thyroid mass and shortness of breath with chest CT positive for bilateral LAD suspicious for sarcoid vs lymphoma. FNA positive for follicular lesion. Clinical Diagnosis: Right thyroid nodule, hilum LAD. Operative Procedure: Right vs total thyroidectomy, mediastinoscopy.

PROCEDURE: SPGD

VERIFIED BY: [REDACTED]

1. "Mediastinal lymph node." A 0.3 cm lymph node.
Frozen section control.
2. "Right thyroid lobe, rule out follicular variant of papillary carcinoma." A 6.0 x 3.5 x 2.0 cm, 14.4 gram, lobe of thyroid containing a 2.0 x 1.5 x 1.0 cm and a 1.0 x 0.6 x 0.6 cm well-defined somewhat lobular nodule. Two additional, tan, poorly defined areas are present. Remainder of parenchyma is dark brown and fairly homogenous. Inked black. Tissue procured.
2A. Large nodule.
Frozen section control.
2B-H. All nodules and areas of tan discoloration submitted.
3. "Mediastinal lymph node level IV R." Several tan soft tissue fragments, 0.5 x 0.5 x 0.3 cm in aggregate.
4. "Delphian lymph node." A 1.0 x 0.5 cm brown soft tissue fragment.
5. "Left lobe thyroid." A 9.8 gram, 6.0 x 3.0 x 2.0 cm lobe of thyroid. Inked black. Fairly homogenous beefy red upon sectioning with no discrete nodules.
5A-C. Sampled.

FROZEN SECTION REPORT:

1. Non-necrotizing granulomatous inflammation; negative for neoplasm.

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: [REDACTED]
NAME: [REDACTED]
BIRTHDATE: [REDACTED]

PATIENT NBR: [REDACTED]
PAT TYPE: [REDACTED]

PAGE #: 3
SEX: F
ADM DATE: [REDACTED]

ACCESSION: [REDACTED]

OPER DATE: [REDACTED]

REQ DOC: [REDACTED]

2. Follicular lesion, suspicious for vascular invasion. [REDACTED]

I, [REDACTED], have reviewed and interpreted the frozen section material at the time it was requested.

I, [REDACTED], have reviewed and interpreted the frozen section material at the time it was requested.

I, [REDACTED], have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

PROCEDURE: SPDX

VERIFIED BY: [REDACTED]

1 & 3. Mediastinal lymph nodes, biopsy: Non-necrotizing granulomas. Negative for neoplasm.

2. Thyroid, right lobe, lobectomy: Papillary carcinoma, follicular variant, 2 cm. Margins free of neoplasm. Lymphocytic thyroiditis. Non-necrotizing granuloma.

Per TSS, follicular variant is >99%.

4. Delphian lymph nodes, biopsy: Negative for neoplasm.

5. Thyroid, left lobe, lobectomy: Lymphocytic thyroiditis.

[REDACTED]

I, [REDACTED], the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file 25fffe56-edde-4252-96d9-f0b51943580b (TCGA-KS-A41I.8D7FB9FA-F66C-431F-985F-90F811FBB487.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).